Gene-level copy-number profile of specimen HCM-BROD-0615-C16-85M from HCMI case HCM-BROD-0615-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.7 years (26,543 days).
Specimen HCM-BROD-0615-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d43b8470-64d4-4760-a5bf-b9a54bdd6a8d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0615-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/d31bf4b8-e8e1-4a15-9ac8-e097ca831853

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,216; copy number 3: 20,605; copy number 4: 15,116; copy number 5: 9,271; copy number 6: 6,962; copy number 7: 2,645; copy number 8: 235; copy number 9: 294; copy number 10: 400; copy number 11: 82; copy number 12: 69; copy number 13: 42; copy number 14: 26; copy number 15: 40; copy number 16: 2; copy number 17: 7; copy number 18: 7; copy number 21: 9; copy number 22: 5; copy number 23: 1; copy number 25: 264; copy number 29: 4; copy number 32: 7; copy number 34: 16; copy number 38: 3; copy number 39: 7; copy number 40: 2; copy number 41: 3; copy number 62: 13; copy number 68: 23; copy number 73: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,213 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,230,030–12,693,020, 9 genes, copy number 8–9: VPS13D, SNORA59A, LINC02766, DHRS3, RNU6ATAC18P, MIR6730, AC254633.1, AADACL4, AC244670.1.
- chr1:143,419,625–145,708,148, 75 genes, copy number 7 (broad region; genes not listed).
- chr2:38,814–40,679,604, 659 genes, copy number 7 (broad region; genes not listed).
- chr2:41,143,780–51,225,575, 163 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr2:134,735,464–135,531,218, 11 genes, copy number 7: CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19, RAB3GAP1, SNORA40B, ZRANB3, G3BP1P1.
- chr3:138,061,990–198,123,232, 1,034 genes, copy number 7 (broad region; genes not listed).
- chr4:36,244,116–36,392,410, 3 genes, copy number 7 (within-gene range 6–7): AC104078.1, DTHD1, AC104078.2.
- chr4:38,758,791–43,410,937, 98 genes, copy number 7–17 (broad region; genes not listed).
- chr4:43,763,134–44,025,516, 5 genes, copy number 7–10 (within-gene range 6–10): AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475.
- chr4:45,995,119–46,510,194, 5 genes, copy number 9–11 (within-gene range 4–11): RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1.
- chr5:8,080,186–9,903,852, 41 genes, copy number 7–8: AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr5:43,874,367–52,581,106, 43 genes, copy number 7–8: AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1.
- chr5:83,471,618–84,384,880, 10 genes, copy number 8–9 (within-gene range 5–9): VCAN, VCAN-AS1, HAPLN1, RN7SKP295, RNU6-620P, AC020899.1, RNU4-11P, ZP3P1, EDIL3, RNU6-448P.
- chr6:10,873,223–12,008,856, 26 genes, copy number 8–12 (within-gene range 5–12): GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4, AL157373.1, AL157373.2.
- chr6:13,357,830–15,113,221, 26 genes, copy number 9–13: GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P.
- chr6:25,652,201–25,885,751, 11 genes, copy number 8: SCGN, PRELID1P2, H2AC1, H2BC1, H2BC2P, H2AC2P, SLC17A4, SLC17A1, SLC17A3, H2AC3P, H2BP5.
- chr6:26,501,221–31,714,072, 357 genes, copy number 8–15 (within-gene range 5–15) (broad region; genes not listed).
- chr6:40,713,411–43,161,719, 84 genes, copy number 8–18 (broad region; genes not listed).
- chr6:43,522,334–44,380,179, 34 genes, copy number 8–13 (within-gene range 3–13): XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1.
- chr6:46,220,736–46,491,972, 2 genes, copy number 12 (within-gene range 12–16): RCAN2, AL359633.1.
- chr6:47,231,532–47,627,263, 6 genes, copy number 8–14: TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1.
- chr6:49,344,800–49,528,078, 5 genes, copy number 13–15: RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3.
- chr7:92,560,758–103,989,658, 321 genes, copy number 21–41 (broad region; genes not listed).
- chr7:115,030,564–117,230,176, 43 genes, copy number 62–73 (within-gene range 3–73): LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2.
- chr7:118,880,103–122,234,903, 31 genes, copy number 9–15: GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1.
- chr8:104,330,324–145,066,685, 580 genes, copy number 7–10 (within-gene range 7–11) (broad region; genes not listed).
- chr9:136,401,922–136,439,845, 3 genes, copy number 7: ENTR1, PMPCA, INPP5E.
- chr10:120,434,983–133,778,699, 228 genes, copy number 7 (broad region; genes not listed).
- chr12:57,674,665–59,064,238, 39 genes, copy number 10: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr12:63,558,913–66,257,434, 79 genes, copy number 7–10 (broad region; genes not listed).
- chr12:120,762,510–121,430,623, 20 genes, copy number 9–12 (within-gene range 6–12): SPPL3, ARF1P2, CLIC1P1, RPL12P33, HNF1A-AS1, HNF1A, C12orf43, OASL, AC079602.2, AC079602.3, SNORA70, AC079602.1, P2RX7, AC069209.2, AC069209.1, P2RX4, CAMKK2, ANAPC5, AC048337.1, RNF34.
- chr12:125,808,668–125,983,665, 5 genes, copy number 7–8: AC005252.2, AC005252.4, AC005252.3, AC005252.1, LINC00939.
- chr13:29,764,371–30,810,645, 28 genes, copy number 7: UBL3, Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398.
- chr13:78,761,175–78,910,542, 4 genes, copy number 7: RPL21P111, LINC00331, HSPD1P8, CCT5P2.
- chr16:17,540,331–18,173,063, 6 genes, copy number 9 (within-gene range 4–9): AC109495.1, AC025277.1, RPL7P47, AC010601.1, AC010601.2, AC091489.1.
- chr16:46,469,341–48,167,238, 45 genes, copy number 7–9 (within-gene range 6–9): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.1, ABCC12, AC096996.2.
- chr17:33,529,787–34,257,203, 21 genes, copy number 12 (within-gene range 12–13): AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2.
- chr17:37,084,992–37,908,063, 20 genes, copy number 11–13: ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P.
- chr17:38,181,659–38,257,192, 3 genes, copy number 8: TBC1D3, NPEPPSP1, Y_RNA.
- chr21:8,759,077–9,914,846, 25 genes, copy number 7–8: LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
